Somatic mutation profile of tumor specimen TCGA-KK-A6E1-01A (aliquot TCGA-KK-A6E1-01A-11D-A30X-08) from TCGA case TCGA-KK-A6E1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.7 years (21,063 days).
Specimen TCGA-KK-A6E1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9e23468-8d7a-40c1-9245-4c0da00fe58b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E1-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E1-11A-21D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5a45795-615c-4a5c-a9cd-1b76a81a53e8

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV50963018; called by muse, mutect2, varscan2
- CCDC70 | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.332); catalogued as COSV54430082; called by muse, mutect2, varscan2
- CNTNAP5 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs576933313, COSV70474495, COSV70480585; called by muse, mutect2, varscan2
- CTNNA2 | c.2636C>T p.T879M (on ENST00000402739 / NM_001282597.3; = p.T831M on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162805213, COSV58132720; called by muse, mutect2, varscan2
- CYP4Z1 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61964748; called by mutect2, varscan2
- GCC2 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1558755166, COSV59175779; called by muse, mutect2, varscan2
- GPBAR1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); catalogued as rs201530699, COSV50307477; called by muse, mutect2, varscan2
- IL11RA | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.804); catalogued as rs201997285, COSV52404891; called by muse, mutect2, varscan2
- MYO3A | c.1462G>T p.G488* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV56328045, COSV56341626; called by muse, mutect2, varscan2
- NEB | c.14441G>A p.R4814H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757278862, COSV51141448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP9 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1414916808, COSV64450515; called by muse, mutect2, varscan2
- RGMB | c.159A>C p.Q53H (on ENST00000513185 / NM_001366508.1; = p.Q94H on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV57565267; called by muse, mutect2, varscan2
- SPTA1 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV63752099; called by muse, mutect2, varscan2
- STK24 | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV64822805; called by muse, mutect2, varscan2
- SULT4A1 | c.454A>T p.M152L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV50780785; called by muse, mutect2, varscan2
- HTR2A | c.1289dup p.N431Efs*11 | Frame Shift Ins (INS) | VAF 36/70 reads (51%) | called by mutect2, varscan2
- NELFE | c.1099_1120del p.Y367Kfs*28 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- PTEN | c.444dup p.Q149Tfs*31 | Frame Shift Ins (INS) | VAF 33/67 reads (49%) | called by mutect2, pindel, varscan2
- CACNA1G | c.3714G>A p.A1238= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs755158469, COSV61724570; called by muse, mutect2, varscan2
- CELA1 | c.114C>T p.Y38= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV53329678; called by muse, mutect2, varscan2
- CTSG | c.387G>T p.L129= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV53535167; called by muse, mutect2, varscan2
- DOCK11 | c.4248T>C p.T1416= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV52237632; called by muse, mutect2, varscan2
- NBEAL2 | c.2574C>A p.I858= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV52756834; called by muse, mutect2, varscan2
- SCG3 | c.171A>G p.T57= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV55020932; called by muse, mutect2, varscan2
